Somatic mutation profile of tumor specimen MMRF_1803_1_BM_CD138pos (aliquot MMRF_1803_1_BM_CD138pos_T1_KBS5U_L06444) from MMRF case MMRF_1803, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.3 years (23,854 days).
Specimen MMRF_1803_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3462269a-ce32-4f15-a5bf-4ba4301d99be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1803_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1803_1_PB_Whole_C2_KBS5U_L06501; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/282cdaca-91eb-43fe-a6c2-b64c5e901fe2

The open-access MAF lists 118 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 25, Intron 17, Silent 16, 5'Flank 6, Nonsense Mutation 3, Frame Shift Del 2, 3'Flank 2, Splice Region 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.3175G>A p.V1059I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1245261794, COSV52219212; called by muse, mutect2, varscan2
- ANO2 | c.2705G>A p.R902H (on ENST00000356134 / NM_001278597.3; = p.R906H on NM_001278596.3) | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192113570, COSV59020943; called by muse, mutect2, varscan2
- ARHGEF10L | c.3071G>C p.S1024T | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.917); catalogued as COSV51433217; called by muse, mutect2, varscan2
- ATM | c.6109G>A p.E2037K | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1448711296, COSV53723692; called by muse, mutect2, varscan2
- C10orf120 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs756538058, COSV100271618; called by muse, mutect2, varscan2
- CNOT3 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 210/336 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99068968; called by muse, mutect2, varscan2
- H2BC12 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV104418618; called by muse, varscan2
- HSPG2 | c.6611G>A p.R2204Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.298); catalogued as rs763073308; called by mutect2, varscan2
- IGKV4-1 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs189743578; called by muse, varscan2
- IGLV3-1 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs537636882; called by muse, mutect2, varscan2
- IGSF9B | c.3539G>T p.S1180I | Missense Mutation (SNP) | VAF 77/138 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs767740632, COSV100317209; called by muse, mutect2, varscan2
- INO80D | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs773913914, COSV101305861; called by muse, mutect2, varscan2
- IQCH | c.2365G>A p.V789M | Missense Mutation (SNP) | VAF 96/307 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs375810750, COSV100245532; called by muse, mutect2, varscan2
- ITGA1 | c.2703C>G p.F901L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV50876572; called by muse, mutect2, varscan2
- METTL3 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398414; called by muse, mutect2, varscan2
- OR1S2 | c.636G>T p.L212F | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs769990765, COSV100223987; called by muse, mutect2, varscan2
- PCDHB3 | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.088); catalogued as rs1554272727, COSV50566362; called by muse, mutect2, varscan2
- SPATA31D1 | c.776G>T p.S259I | Missense Mutation (SNP) | VAF 79/288 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs372453419; called by muse, mutect2, varscan2
- VGLL1 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 91/116 reads (78%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV101034693; called by muse, mutect2, varscan2
- YEATS2 | c.2969C>T p.S990F | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as rs889054388; called by muse, mutect2, varscan2
- ZNF548 | c.1202C>A p.S401* | Nonsense Mutation (SNP) | VAF 53/144 reads (37%) | catalogued as COSV60240257; called by muse, mutect2, varscan2
- ANKRD52 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANO3 | c.2573A>G p.E858G | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ATP5F1A | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BOD1L1 | c.5099G>C p.G1700A | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CDC42BPA | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 147/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CUX2 | c.441G>C p.Q147H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- DSTYK | c.1644C>T p.I548= | Splice Region (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- ENAM | c.2113_2116del p.D705Ifs*36 | Frame Shift Del (DEL) | VAF 11/149 reads (7%) | called by mutect2, pindel
- FBN2 | c.4823G>A p.C1608Y | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FUT5 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- GRXCR1 | c.666A>C p.E222D | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGHV3-16 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 67/80 reads (84%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- LGALS13 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.013); called by muse, mutect2
- MMP27 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MMRN2 | c.82A>C p.S28R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.9557C>T p.A3186V | Missense Mutation (SNP) | VAF 58/417 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MUC19 | c.1219A>T p.R407* | Nonsense Mutation (SNP) | VAF 31/116 reads (27%) | called by muse, mutect2, varscan2
- MYO15B | c.8771C>A p.S2924* | Nonsense Mutation (SNP) | VAF 52/112 reads (46%) | called by muse, mutect2, varscan2
- NEURL2 | c.857G>C p.*286Sext*34 | Nonstop Mutation (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- PCDHGC4 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- PLXNA1 | c.3698T>C p.L1233P | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRR12 | c.3379C>T p.L1127F (on ENST00000615927; = p.L1948F on NM_020719.3) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PRSS33 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBP3 | c.3515G>T p.S1172I | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SLC22A24 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SLC6A20 | c.640_656del p.G214Sfs*48 | Frame Shift Del (DEL) | VAF 48/220 reads (22%) | called by mutect2, pindel, varscan2
- SP9 | c.850T>A p.S284T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VASH1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.01); called by muse, mutect2
- VWA5B1 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- WRN | c.2963G>C p.G988A | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ACSL4 | c.321A>G p.E107= (on ENST00000340800 / NM_022977.2; = p.E66= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/93 reads (92%) | called by muse, mutect2, varscan2
- CACNA1D | c.4632C>T p.V1544= (on ENST00000350061 / NM_001128840.3; = p.V1564= on NM_000720.4) | Silent (SNP) | VAF 61/96 reads (64%) | called by muse, mutect2, varscan2
- CITED4 | c.433C>T p.L145= | Silent (SNP) | VAF 37/90 reads (41%) | called by muse, varscan2
- EFHB | c.1119A>C p.P373= | Silent (SNP) | VAF 48/210 reads (23%) | called by muse, mutect2
- FUBP1 | c.1077A>T p.R359= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- GDPD5 | c.87C>A p.R29= | Silent (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
- GPATCH3 | c.165G>C p.R55= | Silent (SNP) | VAF 9/143 reads (6%) | catalogued as rs1177585646; called by muse, mutect2
- GRIP2 | c.1827T>C p.N609= (on ENST00000619221; = p.N512= on NM_001080423.4) | Silent (SNP) | VAF 4/87 reads (5%) | catalogued as rs1377944990; called by muse, mutect2
- IGKV4-1 | c.276G>A p.G92= | Silent (SNP) | VAF 34/38 reads (89%) | catalogued as rs773802761; called by muse, varscan2
- KANK1 | c.4015A>C p.R1339= | Silent (SNP) | VAF 141/451 reads (31%) | called by muse, mutect2, varscan2
- MUC5B | c.2613G>A p.R871= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs1234247079; called by muse, mutect2, varscan2
- OSER1 | c.831G>A p.L277= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- PRPF6 | c.258G>T p.G86= | Silent (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- RFWD3 | c.2295G>A p.E765= | Silent (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- SLC26A5 | c.759T>C p.N253= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as rs1488557614; called by muse, mutect2
- USP34 | c.2580T>C p.N860= | Silent (SNP) | VAF 45/90 reads (50%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81154181 T>G | 3'Flank (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- AFDN | chr6:167826389 C>T | 5'Flank (SNP) | VAF 30/275 reads (11%) | catalogued as rs1330868462; called by muse, varscan2
- AMOTL2 | c.*405C>T | 3'UTR (SNP) | VAF 52/180 reads (29%) | catalogued as rs541969387; called by muse, mutect2, varscan2
- CCT6A | c.968+60C>G | Intron (SNP) | VAF 51/149 reads (34%) | called by muse, mutect2, varscan2
- CD4 | c.374-171G>C | Intron (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- CFAP43 | c.1442+491G>A | Intron (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- CHKB | c.582-104A>G | Intron (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- CHMP7 | c.*455G>A | 3'UTR (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- CHTF18 | chr16:788491 C>G | 5'Flank (SNP) | VAF 6/18 reads (33%) | catalogued as rs1050803362; called by muse, mutect2
- EDIL3 | c.*1426A>G | 3'UTR (SNP) | VAF 65/117 reads (56%) | catalogued as rs1418739485; called by muse, mutect2, varscan2
- FFAR4 | c.*564A>T | 3'UTR (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- FMO2 | c.*266A>C | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- GABRE | c.*1539G>A | 3'UTR (SNP) | VAF 44/52 reads (85%) | called by muse, mutect2, varscan2
- GH1 | c.171+102C>G | Intron (SNP) | VAF 39/94 reads (41%) | called by muse, mutect2, varscan2
- GTF2A1 | c.*3391T>C | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- HAUS3 | c.*3129A>T | 3'UTR (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- IFNAR1 | c.*3581C>A | 3'UTR (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- IGHJ6 | chr14:105863434 A>G | 5'Flank (SNP) | VAF 7/10 reads (70%) | catalogued as rs1280454556; called by muse, varscan2
- INPP4B | c.136+1962T>G | Intron (SNP) | VAF 75/110 reads (68%) | called by muse, mutect2, varscan2
- IP6K2 | c.202+54C>T | Intron (SNP) | VAF 85/283 reads (30%) | catalogued as rs1304312111; called by muse, mutect2, varscan2
- JMJD6 | chr17:76714237 T>C | 3'Flank (SNP) | VAF 41/112 reads (37%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*26A>C | 3'UTR (SNP) | VAF 67/162 reads (41%) | called by muse, mutect2, varscan2
- KRTAP4-9 | c.*233A>G | 3'UTR (SNP) | VAF 39/82 reads (48%) | catalogued as rs1346299161, COSV101195173; called by muse, mutect2, varscan2
- LIMK1 | c.*29C>T | 3'UTR (SNP) | VAF 38/114 reads (33%) | called by muse, mutect2, varscan2
- LRBA | c.6363+8704C>T | Intron (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- MRPL9 | c.310+175T>C | Intron (SNP) | VAF 26/42 reads (62%) | called by mutect2, varscan2
- NUP160 | c.525+142T>C | Intron (SNP) | VAF 94/322 reads (29%) | called by muse, mutect2, varscan2
- OR10C1 | chr6:29439906 G>T | 5'Flank (SNP) | VAF 104/272 reads (38%) | called by muse, mutect2, varscan2
- POLE | c.3061-649_3061-646dup | Intron (INS) | VAF 26/72 reads (36%) | called by mutect2, varscan2
- POMT2 | c.*1468G>A | 3'UTR (SNP) | VAF 52/67 reads (78%) | called by muse, mutect2, varscan2
- PRAC1 | c.*71T>A | 3'UTR (SNP) | VAF 22/51 reads (43%) | catalogued as rs998589120, COSV99285011; called by muse, mutect2, varscan2
- PRTG | c.*5379G>T | 3'UTR (SNP) | VAF 45/165 reads (27%) | called by muse, mutect2, varscan2
- RBBP9 | c.*2811C>A | 3'UTR (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- RBM14 | c.*409C>A | 3'UTR (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- RFC2 | chr7:74254429 C>A | 5'Flank (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- RIPK1 | c.*182C>T | 3'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- RPL35 | c.3+71G>C | Intron (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- SEMA3D | c.*2216G>T | 3'UTR (SNP) | VAF 66/118 reads (56%) | called by muse, mutect2, varscan2
- SLAMF7 | c.873+109A>G | Intron (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2
- SLC30A4 | c.*555A>C | 3'UTR (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- SLC4A7 | c.*2008T>C | 3'UTR (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- SORCS1 | c.3371+253T>C | Intron (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- SP3 | c.*2935C>G | 3'UTR (SNP) | VAF 38/84 reads (45%) | called by muse, mutect2, varscan2
- STRADA | c.859-396T>A | Intron (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- TAPT1 | chr4:16227352 G>C | 5'Flank (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- TSHZ2 | c.-607G>A | 5'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, varscan2
- UBXN10 | c.*2621G>C | 3'UTR (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- UTP25 | c.2027+202G>A | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- WDR48 | c.*379C>T | 3'UTR (SNP) | VAF 46/147 reads (31%) | catalogued as rs921179350; called by muse, mutect2, varscan2
- ZNF286A | c.*2522A>C | 3'UTR (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- ZNF517 | c.34-111C>T | Intron (SNP) | VAF 8/35 reads (23%) | catalogued as rs1167558924; called by muse, mutect2
